TARGET case TARGET-30-PAMBMJ — Neuroblastoma (TARGET-NBL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neuroepitheliomatous Neoplasms; Primary site: Peripheral nerves and autonomic nervous system. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/b82882ff-ab81-5150-bb71-b35bb607d35b

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 2 years; Vital status: Dead; Days to death: 491 days (1.3 years).

Diagnoses (1)
1. Neuroblastoma, NOS: ICD-O-3 morphology code: 9500/3; ICD-10 code: C47.6; Tissue or organ of origin: Peripheral nerves and autonomic nervous system of trunk, NOS; Classification of tumor: primary; Age at diagnosis: 2.6 years (954 days); Year of diagnosis: 2003; Days to last follow up: 491 days (1.3 years); Cog neuroblastoma risk group: High Risk; Inpc grade: Undifferentiated or Poorly Differentiated; INSS stage: Stage 4; Mitosis karyorrhexis index: Intermediate.
   Pathology details: Necrosis percent: 0; Percent tumor nuclei: 100.
   Treatment given: Protocol identifier: A3973.
   Treatment given: Protocol identifier: ANBL00B1.

Follow-up (4 entries)
- Days to follow up: 449 days (1.2 years); Progression or recurrence anatomic site: Bone marrow; Days to first event: 449 days (1.2 years); First event: Relapse.
- Days to follow up: 449 days (1.2 years); Progression or recurrence anatomic site: Bone, NOS.
- Days to follow up: 449 days (1.2 years); Progression or recurrence anatomic site: Skin of scalp and neck.
- Days to follow up: 491 days (1.3 years); Year of follow up: 2004.

Molecular and laboratory tests
- MYCN amplification: Amplified.
- Test: Abnormal, NOS; Ploidy: Hyperdiploid.

Biospecimens (2 samples)
- Sample TARGET-30-PAMBMJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
- Sample TARGET-30-PAMBMJ-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_NBL_ClinicalData_Discovery_20230523.xlsx (sheet Clinical Data):
- Overall Survival Time in Days: 491
- Protocol: ANBL00B1, A3973
- Ploidy: Hyperdiploid (DI>1)
- Ploidy Value: 1.39
- Histology: Unfavorable
- ICDO Description: Peripheral nerves and Autonomic nervous system of trunk, NOS Peripheral nerves and Autonomic nervous system of (see list under C47): . Back . Flank . Trunk Lumbar nerve
- Percent Necrosis: 0
- Percent Tumor v/s Stroma: 80/20
- Site of Relapse: Bone; Bone Marrow; Other, specify: Mass extended into the scalp.
